Somatic mutation profile of tumor specimen TCGA-MI-A75I-01A (aliquot TCGA-MI-A75I-01A-11D-A32G-10) from TCGA case TCGA-MI-A75I, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-MI-A75I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fea921c-d69f-4a6c-b3e1-139d4683b4ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MI-A75I-10A (Blood Derived Normal), aliquot TCGA-MI-A75I-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58ea6cca-ec98-47ca-8da9-0de23383f589

The open-access MAF lists 196 somatic variants for this specimen: 147 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 44, Nonsense Mutation 8, Frame Shift Del 6, Splice Site 4, Intron 3, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2221A>C p.K741Q | Missense Mutation (SNP) | VAF 57/161 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1380834335, COSV59207072, COSV59211907, COSV59219639; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.940T>G p.Y314D | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs533220517, COSV56894319; called by muse, mutect2, varscan2
- ACSM2B | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143500332, COSV61657473; called by muse, mutect2, varscan2
- ADH1A | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52924707; called by muse, mutect2, varscan2
- AFF2 | c.3919G>C p.D1307H | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53977124, COSV53985327; called by muse, mutect2, varscan2
- AGAP3 | c.878G>T p.G293V (on ENST00000622464; = p.G329V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV58994237; called by muse, mutect2, varscan2
- AHR | c.2048A>G p.Q683R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV54122835; called by muse, mutect2, varscan2
- AKAP9 | c.4693-2A>C p.X1565_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV62343586; called by muse, mutect2, varscan2
- AMER3 | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58466139; called by muse, mutect2, varscan2
- AMPH | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57739538; called by muse, mutect2, varscan2
- ANO7 | c.1271T>C p.V424A (on ENST00000274979; = p.V370A on NM_001370694.2) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51470651; called by muse, mutect2, varscan2
- APOBEC3B | c.1123del p.A375Pfs*23 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as COSV59840816; called by mutect2, varscan2
- ARC | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100751650, COSV63078381; called by muse, mutect2
- ARHGEF37 | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345727536, COSV61368517; called by muse, mutect2, varscan2
- ATAD2B | c.2657G>T p.R886I | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.481); catalogued as COSV53197327; called by muse, mutect2, varscan2
- C10orf90 | c.1925G>A p.C642Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as rs776633093, COSV52953251, COSV99503210; called by mutect2, varscan2
- C12orf42 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59381385; called by muse, mutect2, varscan2
- C1GALT1C1L | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV56752201; called by muse, mutect2, varscan2
- C2CD2 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as COSV61598800, COSV61599180; called by muse, mutect2, varscan2
- C4orf45 | c.48A>C p.K16N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV71700981; called by muse, mutect2, varscan2
- CACNA1A | c.4734G>A p.M1578I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV64195548; called by muse, mutect2, varscan2
- CALR3 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54169293; called by muse, mutect2, varscan2
- CCDC178 | c.2435T>A p.F812Y (on ENST00000383096 / NM_001105528.3; = p.F774Y on NM_198995.3) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55769264; called by muse, mutect2, varscan2
- CCDC65 | c.300+2T>C p.X100_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV57195341; called by muse, mutect2, varscan2
- CCNO | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1554020012, COSV57004550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCSER1 | c.1991A>T p.E664V | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV61422943; called by muse, mutect2, varscan2
- CDK5RAP1 | c.976G>C p.E326Q (on ENST00000357886 / NM_001365728.1; = p.E312Q on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as COSV100212265, COSV59426597; called by muse, mutect2, varscan2
- CECR2 | c.1718_1719insG p.W574Lfs*124 (on ENST00000342247 / NM_001290047.2; = p.W391Lfs*124 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | catalogued as COSV99377374; called by mutect2, pindel, varscan2
- CLASP2 | c.1949A>G p.D650G | Missense Mutation (SNP) | VAF 125/335 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.114); catalogued as COSV56280395; called by muse, mutect2, varscan2
- CLCA2 | c.1940A>T p.E647V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV65286830; called by mutect2, varscan2
- CMPK2 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV56774438; called by muse, mutect2, varscan2
- CNTN2 | c.2555G>T p.W852L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59349489; called by muse, mutect2, varscan2
- COL4A2 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV64627184; called by muse, mutect2, varscan2
- COX6B1 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV55837602; called by muse, mutect2
- CR2 | c.1354C>G p.Q452E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV65507159; called by muse, mutect2, varscan2
- CSMD3 | c.8294C>A p.P2765H (on ENST00000297405 / NM_001363185.1; = p.P2596H on NM_052900.3) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52095614, COSV52154468; called by muse, mutect2, varscan2
- CXCL14 | c.91C>T p.R31C (on ENST00000337225; = p.R19C on NM_004887.5) | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV61499201; called by muse, mutect2, varscan2
- CXCR3 | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV65461807; called by muse, mutect2, varscan2
- DDX3Y | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV60176817; called by muse, mutect2, varscan2
- DEDD2 | c.505A>T p.R169* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV60141643; called by muse, mutect2
- DENND2A | c.2750T>C p.F917S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV52050185; called by muse, mutect2, varscan2
- DIRAS1 | c.206C>G p.P69R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV60215425; called by muse, mutect2, varscan2
- DISP3 | c.1336G>T p.G446W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779406722, COSV53825227; called by muse, varscan2
- DPY19L1 | c.1351-2A>G p.X451_splice | Splice Site (SNP) | VAF 78/251 reads (31%) | catalogued as COSV60581805; called by muse, mutect2, varscan2
- ENTPD1 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV64601161; called by muse, mutect2, varscan2
- ERMN | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68075165; called by muse, mutect2
- FAT3 | c.12662T>C p.V4221A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53098791; called by muse, mutect2, varscan2
- FERMT1 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.754); catalogued as rs773618744, COSV54092356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FKBP4 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV50009456; called by muse, mutect2
- FMNL2 | c.1154C>A p.A385D | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56493357; called by muse, mutect2, varscan2
- FOXD3 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.122); catalogued as COSV64379892; called by muse, mutect2, varscan2
- GABBR1 | c.2479T>C p.S827P | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV63541990; called by muse, mutect2, varscan2
- GLI2 | c.4306A>T p.M1436L (on ENST00000361492 / NM_001374353.1; = p.M1453L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100083747, COSV58039558; called by muse, mutect2, varscan2
- GPR156 | c.2359G>T p.G787W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs375340933, COSV59939352; called by muse, mutect2, varscan2
- GRIA2 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749173821, COSV52387752; called by muse, mutect2, varscan2
- GRIA4 | c.1948C>G p.R650G | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891060; called by muse, mutect2, varscan2
- GUCY1B1 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100025561, COSV52374982; called by muse, mutect2, varscan2
- H2AZ1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV56454886; called by muse, mutect2, varscan2
- HEPACAM2 | c.411G>T p.K137N (on ENST00000394468 / NM_001039372.4; = p.K125N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV59059580; called by muse, mutect2, varscan2
- HOXB7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770931876, COSV53310001; called by muse, mutect2, varscan2
- IQCG | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV54561581; called by muse, mutect2, varscan2
- JARID2 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as COSV59188100; called by muse, mutect2
- KDM6A | c.443+2T>G p.X148_splice | Splice Site (SNP) | VAF 26/40 reads (65%) | catalogued as COSV65039144; called by muse, mutect2, varscan2
- KIF1C | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57904066; called by muse, mutect2, varscan2
- KIF4A | c.1799A>G p.K600R | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV65542642; called by muse, mutect2, varscan2
- KIR2DL1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.379); catalogued as COSV52408816; called by muse, mutect2, varscan2
- KRTAP5-2 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV69014845; called by muse, mutect2, varscan2
- LAMA1 | c.2080A>T p.S694C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV67535284; called by muse, mutect2, varscan2
- LPIN1 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV56764516; called by muse, mutect2, varscan2
- LRP1 | c.12433C>T p.P4145S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1041474728, COSV54508044; called by muse, mutect2, varscan2
- LRP2 | c.12675C>A p.F4225L | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV55540335, COSV55549375; called by muse, mutect2, varscan2
- LRRK2 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 55/130 reads (42%) | catalogued as COSV100109596; called by muse, mutect2, varscan2
- MAG | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.969); catalogued as COSV62700086; called by muse, mutect2, varscan2
- MAGEB4 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV64396936; called by muse, mutect2, varscan2
- MAGI2 | c.177A>C p.K59N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV62647011; called by muse, mutect2
- MDM1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV57445417; called by muse, mutect2, varscan2
- MPO | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51858188; called by muse, mutect2, varscan2
- MROH5 | c.3058A>T p.I1020F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV71301094; called by muse, mutect2, varscan2
- MRPL47 | c.623T>G p.F208C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52022879; called by muse, mutect2, varscan2
- MTA1 | c.1382C>G p.P461R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV58756716; called by muse, mutect2, varscan2
- MUC17 | c.9129A>T p.E3043D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.636); catalogued as rs1211394305, COSV60285794; called by muse, mutect2, varscan2
- MYO18A | c.4942T>G p.F1648V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62865220; called by muse, mutect2, varscan2
- NCAPD3 | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV73258264; called by muse, mutect2, varscan2
- NECAP1 | c.148A>T p.T50S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV60249144; called by muse, mutect2, varscan2
- NLGN4Y | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 83/135 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59295428; called by muse, mutect2, varscan2
- NTM | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV66204510; called by muse, mutect2, varscan2
- OR2S2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV59529815; called by muse, mutect2, varscan2
- OR8K3 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs759115963, COSV57131245; called by muse, mutect2, varscan2
- OVCH1 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV58961782; called by muse, mutect2, varscan2
- OVCH1 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as COSV58961791; called by muse, mutect2, varscan2
- PADI4 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772971178, COSV64923785; called by muse, mutect2, varscan2
- PAK5 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62025425; called by muse, mutect2, varscan2
- PATJ | c.2929A>C p.N977H | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57160081; called by muse, mutect2, varscan2
- PCDHA7 | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as rs1454301862, COSV65336115; called by muse, mutect2, varscan2
- PKN1 | c.2417A>T p.Y806F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV52874928; called by muse, mutect2, varscan2
- PKNOX2 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53544093; called by muse, mutect2, varscan2
- PLD5 | c.1129A>T p.R377* (on ENST00000442594; = p.R315* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 72/190 reads (38%) | catalogued as COSV100139513; called by muse, varscan2
- PLXNA3 | c.5043C>A p.H1681Q | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63753772; called by muse, mutect2, varscan2
- PNPLA7 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52997490; called by mutect2, varscan2
- POMC | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203639783, COSV53034666; called by muse, mutect2, varscan2
- PRDM1 | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV64848871; called by muse, mutect2, varscan2
- PREX1 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs1197607003, COSV64250598; called by muse, mutect2, varscan2
- PRTG | c.3137A>G p.K1046R | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV66837613; called by muse, mutect2, varscan2
- PTCH2 | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV64710712; called by muse, varscan2
- RADIL | c.2076C>G p.H692Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1386982780, COSV67650859; called by muse, mutect2, varscan2
- RASGRF1 | c.950T>A p.L317Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69178143; called by muse, mutect2, varscan2
- RASGRF1 | c.800T>G p.L267R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV69178150; called by muse, mutect2, varscan2
- RP1 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs751318405, COSV55114717; called by muse, mutect2, varscan2
- SLC45A4 | c.643G>T p.G215W (on ENST00000517878 / NM_001286646.2; = p.G164W on NM_001080431.2) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50136169; called by muse, mutect2, varscan2
- SLC6A14 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV100903097; called by muse, mutect2
- SPAG6 | c.862del p.L288Wfs*2 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as COSV57618594; called by mutect2, pindel*, varscan2
- SSX2IP | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60552236; called by muse, mutect2, varscan2
- STK31 | c.2170A>G p.M724V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1274471524, COSV63455103; called by muse, mutect2, varscan2
- STMN1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 41/115 reads (36%) | catalogued as COSV63481246, COSV63481248; called by muse, mutect2, varscan2
- TBCD | c.1604A>T p.D535V | Missense Mutation (SNP) | VAF 216/401 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV62799793; called by muse, mutect2, varscan2
- TBR1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV67417682; called by muse, mutect2, varscan2
- TENM2 | c.4804C>G p.H1602D (on ENST00000518659 / NM_001122679.2; = p.H1363D on NM_001080428.3) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV69127785; called by muse, mutect2, varscan2
- TGFB2 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV65108886; called by muse, mutect2, varscan2
- TJP1 | c.3757G>T p.E1253* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV62041179; called by muse, mutect2, varscan2
- TM6SF1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV51943928; called by muse, mutect2, varscan2
- TRPM6 | c.2953G>C p.A985P | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV62507487; called by muse, mutect2, varscan2
- TSC2 | c.2355+1del | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV99052774; called by mutect2, pindel, varscan2
- TTBK1 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52490231; called by muse, mutect2, varscan2
- TTN | c.44167A>G p.T14723A (on ENST00000591111; = p.T7299A on NM_003319.4) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | PolyPhen probably damaging (0.994); catalogued as COSV59992178; called by muse, mutect2, varscan2
- TTN | c.39664A>G p.T13222A (on ENST00000591111; = p.T5798A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | PolyPhen benign (0.373); catalogued as COSV59992201; called by muse, mutect2, varscan2
- TXNDC2 | c.470T>C p.I157T (on ENST00000306084 / NM_001098529.2; = p.I90T on NM_032243.6) | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.565); catalogued as COSV60152871; called by muse, mutect2, varscan2
- USP19 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.045); catalogued as COSV60045645; called by muse, varscan2
- WSCD2 | c.209T>C p.M70T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54581255; called by muse, mutect2, varscan2
- WTAP | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); catalogued as rs1192775013, COSV61609988; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.81); catalogued as COSV60156393; called by muse, mutect2
- ZNF189 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52275000; called by muse, mutect2, varscan2
- ZNF266 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1411655596, COSV63221912; called by muse, mutect2, varscan2
- ZNF274 | c.293C>G p.P98R (on ENST00000610905; = p.P66R on NM_016325.3) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV58763958; called by muse, mutect2, varscan2
- ZNF398 | c.1453T>C p.C485R (on ENST00000475153 / NM_170686.3; = p.C314R on NM_020781.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60065075; called by muse, mutect2, varscan2
- ZNF468 | c.116A>C p.E39A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54694209; called by muse, mutect2, varscan2
- ZNF571 | c.484A>T p.N162Y | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60732901; called by muse, mutect2, varscan2
- ZNF653 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs377200586; called by muse, mutect2, varscan2
- ZRANB1 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62842124; called by muse, mutect2, varscan2
- A2M | c.3147T>A p.F1049L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ATF6 | c.687dup p.G230Rfs*38 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- CDH11 | c.797del p.P266Qfs*22 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel*, varscan2
- OPCML | c.385del p.H129Tfs*2 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.881T>A p.I294N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLA2R1 | c.579_605del p.R194_L202del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- PRAMEF18 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 114/611 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPEF1 | c.436del p.R146Efs*60 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2274G>A p.Q758= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV53169802, COSV99536615; called by muse, mutect2, varscan2
- ATG4B | c.165G>A p.R55= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs762783407, COSV60350534; called by muse, mutect2, varscan2
- BTN3A1 | c.912A>G p.T304= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV50024656; called by muse, mutect2, varscan2
- CAMKK1 | c.975C>A p.S325= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV50115337, COSV50119047; called by mutect2, varscan2
- CD1E | c.816C>A p.T272= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV63770714; called by muse, mutect2, varscan2
- CLCA4 | c.480C>G p.L160= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as COSV55367612; called by muse, mutect2, varscan2
- DGKB | c.486C>T p.D162= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV51775651; called by muse, mutect2, varscan2
- DSP | c.1791A>T p.S597= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV65792299; called by muse, mutect2, varscan2
- EIF3A | c.3474C>T p.P1158= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV64961068; called by muse, mutect2, varscan2
- FASN | c.5718G>A p.Q1906= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV60753201; called by muse, mutect2, varscan2
- FBN1 | c.4263C>T p.L1421= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV57314405; called by muse, mutect2, varscan2
- GLS2 | c.1146T>C p.S382= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV57665412; called by muse, mutect2, varscan2
- GPR62 | c.1071C>A p.P357= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV59054358; called by muse, mutect2, varscan2
- GRIA3 | c.1941C>T p.S647= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1410038373, COSV99989454; called by muse, mutect2
- HOXC8 | c.267T>C p.Y89= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs777616754, COSV50000987; called by muse, mutect2, varscan2
- IFT88 | c.870A>G p.T290= (on ENST00000319980 / NM_001318493.2; = p.T281= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as rs758388595, COSV60672650; called by muse, mutect2, varscan2
- IGSF11 | c.291C>T p.T97= (on ENST00000393775 / NM_001015887.3; = p.T96= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV61168431; called by muse, mutect2, varscan2
- IPO9 | c.492T>C p.H164= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV64233428; called by muse, mutect2, varscan2
- KCNK2 | c.312C>G p.S104= (on ENST00000444842 / NM_001017425.3; = p.S89= on NM_014217.4) | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV67204899, COSV67208563; called by muse, mutect2, varscan2
- KDR | c.2532C>G p.A844= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1346329555, COSV55762659; called by muse, mutect2, varscan2
- LHX8 | c.453A>G p.R151= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV53955686; called by muse, mutect2, varscan2
- LRFN5 | c.595C>A p.R199= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs140770648, COSV53251881, COSV53254685; called by muse, mutect2, varscan2
- LRRCC1 | c.2325A>G p.Q775= | Silent (SNP) | VAF 38/223 reads (17%) | catalogued as COSV64483182; called by muse, mutect2, varscan2
- MAT2A | c.987T>C p.S329= | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as COSV52087888; called by muse, mutect2, varscan2
- MMP16 | c.1560A>T p.G520= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV54160160; called by muse, mutect2, varscan2
- MROH5 | c.997C>T p.L333= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV71301098; called by muse, mutect2, varscan2
- MTTP | c.1956G>A p.Q652= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as rs369415595; called by muse, mutect2, varscan2
- MUC5B | c.7644C>A p.T2548= | Silent (SNP) | VAF 64/217 reads (29%) | catalogued as COSV101500147; called by muse, mutect2, varscan2
- PCDHB9 | c.882C>A p.I294= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- PDZD7 | c.457C>T p.L153= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV64645945; called by muse, mutect2, varscan2
- PHYKPL | c.846C>T p.N282= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as rs760765398, COSV57423684; called by muse, mutect2, varscan2
- PLA2G7 | c.411T>A p.P137= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs1248455137, COSV51259742; called by muse, mutect2, varscan2
- PLEKHA6 | c.2244C>T p.I748= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV55332294, COSV55338644; called by muse, mutect2, varscan2
- PRKDC | c.9805A>C p.R3269= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV58049460; called by muse, mutect2, varscan2
- RECK | c.2718A>G p.A906= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV65035133; called by muse, mutect2, varscan2
- RHOA | c.324C>T p.P108= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs749741822, COSV69042250; called by muse, mutect2, varscan2
- SLC6A2 | c.855C>T p.P285= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs180935423, COSV54915084; called by muse, mutect2, varscan2
- SPEG | c.3879T>C p.A1293= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV56666981; called by muse, mutect2, varscan2
- SRP54 | c.1230G>C p.S410= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV53739190, COSV53741313; called by muse, mutect2, varscan2
- TBX2 | c.1917C>T p.T639= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as rs768086181, COSV53598441; called by muse, mutect2, varscan2
- TBX22 | c.915T>G p.T305= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV64785613; called by muse, mutect2, varscan2
- TENM4 | c.8106G>C p.A2702= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs769658072, COSV53611615, COSV53621848; called by muse, mutect2, varscan2
- USP21 | c.774C>T p.L258= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs768269159, COSV57087866; called by muse, mutect2, varscan2
- USP25 | c.2889C>T p.V963= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as COSV53483327; called by muse, mutect2, varscan2
- EPHA6 | c.1895-8925A>C | Intron (SNP) | VAF 29/64 reads (45%) | catalogued as COSV67568522; called by muse, mutect2, varscan2
- EXOC3 | chr5:442494 G>A | 5'Flank (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- HERC2P3 | n.167T>A | RNA (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- TNK2 | c.1543+588G>A | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as rs770562169, COSV57368173; called by muse, mutect2, varscan2
- TRIM36 | c.64-7421C>T | Intron (SNP) | VAF 52/120 reads (43%) | catalogued as rs1285432262, COSV56689671; called by muse, mutect2, varscan2
